Surgical pathology report (de-identified scan), TCGA case TCGA-44-4112, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-4112-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Level 3 lymph node
- B. Level 10
- C. Middle lobe
- D. Level 10
- E. RUL
- F. R4
- G. Subcarinal

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung carcinoma.

GROSS DESCRIPTION

- A. Received fresh labeled "level 3 lymph node" are two soft tan-gray tissues in keeping with lymph nodes measuring 0.8 cm in greatest dimension and 2.4 x 1.3 x 0.6 cm. The specimens are bisected and entirely submitted independently in two blocks (one bisected node per cassette). AS-2.
- B. Received fresh labeled "level 10" is a slightly rubbery, 2.4 x 1.8 x 1.4 cm tan gray-red tissue in keeping with lymph node which is sectioned and entirely submitted in two blocks. AS-2.
- C. Received fresh labeled "middle lobe" is a slightly fragmented, 1.4 x 0.9 x 0.6 cm soft tan gray-black tissue which is bisected and entirely submitted in one block. AS-1.
- D. Received fresh labeled "level 10" are three intact to fragmented soft tan gray-black tissues in keeping with lymph nodes measuring up to 1.8 x 1.6 x 0.7 cm. The specimens are entirely submitted in three blocks as labeled. AS-3.

BLOCK SUMMARY: 1 - Two whole lymph nodes; 2,3 - sectioned largest lymph node. [REDACTED]

- E. Received fresh labeled "RUL" is a 362 gram, 17 x 12.5 x

GROSS DESCRIPTION

- 4.3 cm lobectomy specimen with attached 1 cm in length, 1.3 x 0.9 cm in diameter bronchial stump. The pleura is focally retracted with a subjacent palpable mass along the medial inferior aspect. On sectioning, the aforementioned palpable mass is well circumscribed, pale tan white-gray and measures 5 x 4.6 x 4 cm. The lesion extends to within less than 0.1 cm of the inked pleural surface. A portion of the tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The tumor is greater than 3.8 cm from the bronchial stump margin. The parenchyma

[page 2 of 3]
[REDACTED]

throughout the remainder of the specimen is spongiform to focally consolidated tan pink-red. No additional mass lesion or abnormality

is identified. A slightly fragmented, 1.4 cm in greatest dimension tan pink-gray to tan-black tissue in keeping with lymph node is recovered from the hilum. Representative sections are submitted in eleven blocks as labeled. RS-11.

5 BLOCK SUMMARY: 1 - Bronchial stump margin; 2 - vascular margin; 3 - tumor to inked pleural surface; 6 - tumor to normal parenchyma; 7-10 - random from remainder of specimen; 11 - bisected perihilar lymph node. [REDACTED]

F. Received fresh, labeled "R4" is a 4.6 x 3.4 x 1.3 cm. aggregate of soft lobulated golden yellow adipose tissue. Several apparent fragmented soft tan gold to gray black tissues in keeping with lymph nodes measuring up to 3.3 cm. in greatest dimension are present. The specimen is entirely submitted in four blocks as labeled. AS-4.

BLOCK SUMMARY: 1 - Seven whole presumptive lymph nodes; 2,3 - one bisected presumptive lymph node (one-half per cassette); 4 - residual adipose tissue.

G. Received fresh, labeled "subcarinal" are two intact to

GROSS DESCRIPTION

slightly fragmented soft tan gray-black tissues in keeping with lymph nodes measuring up to 3 cm. in greatest dimension. The specimens are bisected and entirely submitted in three blocks as labeled. RS-3.

BLOCK SUMMARY: 1 - One bisected node; 2,3 - one bisected node (one-half per cassette). [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Primary tumor (pT): The tumor measures 5 cm in dimension and invades into the pleura, pT2a.

Margins of resection: Negative for tumor

Direct extension of tumor: Tumor invades into the pleura and is focally present on the pleural surface.

Vessel invasion: Present

Regional lymph nodes: Metastatic carcinoma is identified in a hilar lymph node and also in two of 10 R4 lymph nodes. The other submitted

[page 3 of 3]
nodes are negative for tumor.
Distant metastasis: PMX.

3x5, 5x1, 4x1

DIAGNOSIS

- A. Lymph node, level 3, excision -- Two lymph nodes negative for metastatic carcinoma (0/2).
- B. Lymph node, level 10, excision -- One lymph node negative for metastatic carcinoma (0/1).
- C. Lymph node, middle lobe, excision -- One lymph node negative for metastatic carcinoma (0/1).

DIAGNOSIS

- D. Lymph node, level 10, excision -- Three lymph nodes negative for metastatic carcinoma (0/3).
- E. Lung, right upper lobe, excision -- Invasive poorly differentiated adenocarcinoma (see tumor characteristics in the microscopic description). Tumor extends to the pleural surface.
One of four hilar lymph nodes is positive for metastatic carcinoma (1/4).
- F. Lymph node, R4, excision -- Two of 10 lymph nodes positive for metastatic carcinoma (2/10).
The largest metastasis measures 0.7 cm in dimension.
Extracapsular extension by tumor is identified.
- G. Lymph node, subcarinal, excision -- Two lymph nodes negative for metastatic carcinoma (0/2).

T08000, P11000, T08000, D76720, T28100, M81403, M80001, T08320,
M80103, F89050

--- End Of Report ---

Source: NCI Genomic Data Commons file 0e1557d4-679d-4a20-ae1a-13a9b16f7043 (TCGA-44-4112.9F214C90-F9A8-458C-8A53-CA8E8B09A2B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).